TCGA case TCGA-77-A5G1 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf6bab32-98bb-4e09-a7fe-c5c1779a5f60

Demographics
Sex at birth: male; Country of residence at enrollment: Australia; Age at index: 75 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,555 days); Year of diagnosis: 2002; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 4,026 days (11.0 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 81.5 years (29,752 days); Days to diagnosis: 2,197 days (6.0 years); Prior treatment: Yes.

Follow-up (2 entries)
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contacts recording only the day: day 3,714, day 4,026.

Other clinical attributes
- DLCO (% of predicted): 83; FEV1/FVC before bronchodilator (%): 67; FEV1 before bronchodilator (% of reference): 79.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 53; Tobacco smoking onset year: 1942; Tobacco smoking quit year: 1995.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-77-A5G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 250 mg.
  Slide TCGA-77-A5G1-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-77-A5G1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-77-A5G1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- New tumor event, New neoplasm event types: New tumor event type: New Primary Tumor.
- New tumor event, Progression determined by list: New tumor event diagnosis evidence: Biopsy with Histologic Confirmation.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,026 days; disease-specific survival: no event (censored), 4,026 days; disease-free interval: no event (censored), 4,026 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,197 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-77-A5G1-01A-11D-A27J-01): tumor purity 0.25, ploidy 1.85, whole-genome doublings 0.
